Gene-level copy-number profile of tumor specimen MP2PRT-PARPJK-TMP1-A from MP2PRT case MP2PRT-PARPJK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (613 days).
Specimen MP2PRT-PARPJK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 71743657-9760-442f-9c40-aef432600073.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARPJK-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/abaf11a5-5f32-41cc-815c-31b4f3dc0f52

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 49; copy number 2: 43,293; copy number 3: 14,953; copy number 4: 30; copy number 5: 16; copy number 6: 22; copy number 7: 19.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 57 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,965,451–22,418,657, 36 genes, copy number 5–7: TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3.
- chr14:22,455,249–22,493,990, 20 genes, copy number 5–7 (within-gene range 2–8): TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45.
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.

Autosomal genes at a single copy (total copy number 1): 49. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
